MMRF case MMRF_1763 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4deed062-2b30-4cc6-868e-3a824decf8c9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.4 years (19,498 days); ISS stage: I; Days to last known disease status: 1,108 days (3.0 years); Days to last follow up: 1,108 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 38 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 54 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 131 days; Days to treatment end: 131 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 764 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 769 days (2.1 years); Days to treatment end: 937 days (2.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,077 days (2.9 years); Days to treatment end: 1,077 days (2.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.93 g/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 21.8 g/L; Immunoglobulin M 0.385 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 8.4 g/dL; Glucose 6.11 mmol/L.
- Day 99 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.691 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.83 mmol/L.
- Day 183 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.578 mg/dL; Immunoglobulin G 4.95 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 274 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.526 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 140 ×10⁹/L.
- Day 377 (ECOG 0): Hemoglobin 8.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 159 ×10⁹/L.
- Day 428 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.656 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.542 mg/dL; Immunoglobulin G 6.36 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.94 mmol/L.
- Day 517 (ECOG 0): Hemoglobin 8.68 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 160 ×10⁹/L.
- Day 729 (ECOG 0): M Protein 0.229 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 4.91 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 7.4 g/dL; Glucose 4.73 mmol/L.
- Day 827 (ECOG 3): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.55 mg/dL; Immunoglobulin G 4.66 g/L; Immunoglobulin A 8.64 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.79 mmol/L.
- Day 932 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 4.08 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.23 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 974 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 4.74 g/L; Immunoglobulin A 1.63 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.25 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 1,030 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 1.75 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 1,108 (ECOG 1): Hemoglobin 5.83 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 77 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1763_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1763_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
